Somatic mutation profile of tumor specimen TCGA-29-1763-01A (aliquot TCGA-29-1763-01A-02W-0633-09) from TCGA case TCGA-29-1763, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 43.9 years (16,021 days).
Specimen TCGA-29-1763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23931ad4-4ef0-4d2f-95de-e785998d627a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1763-10A (Blood Derived Normal), aliquot TCGA-29-1763-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02ea3fb7-0b12-4c7a-a067-e36cf1e0ce5a

The open-access MAF lists 141 somatic variants for this specimen: 101 protein-altering or splice-affecting, 39 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 39, Nonsense Mutation 5, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 3, In Frame Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 122/170 reads (72%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABRA | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 19/438 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs551422006, COSV100357667, COSV61732308; called by muse, mutect2
- ACACB | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 39/175 reads (22%) | catalogued as COSV58147222; called by muse, mutect2, varscan2
- ACSM6 | c.821T>C p.L274S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1226694460, COSV58980826; called by muse, mutect2, varscan2
- ADAM19 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV57433518; called by muse, mutect2, varscan2
- AEN | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.641); catalogued as rs368922473; called by muse, mutect2, varscan2
- AKAP13 | c.5651C>T p.T1884I (on ENST00000394518 / NM_007200.5; = p.T1888I on NM_006738.6) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1389761177, COSV63470590; called by muse, mutect2, varscan2
- ANK2 | c.4672G>T p.D1558Y | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52189828; called by muse, mutect2, varscan2
- AP2M1 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491003; called by muse, mutect2
- BICC1 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54067141; called by muse, mutect2, varscan2
- BSND | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100987663; called by muse, varscan2
- CABYR | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV100510201; called by muse, mutect2, varscan2
- CACNA2D1 | c.2773G>T p.A925S (on ENST00000356253 / NM_001366867.1; = p.A913S on NM_000722.4) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV62393095; called by muse, mutect2, varscan2
- CATSPERG | c.3103G>T p.V1035L | Missense Mutation (SNP) | VAF 172/543 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53054060; called by muse, mutect2, varscan2
- CCT5 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54725581; called by muse, mutect2, varscan2
- CD1D | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 320/452 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV63810105; called by muse, mutect2, varscan2
- CDKL1 | c.548dup p.V184Gfs*12 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs766143608; called by pindel, varscan2
- CENPE | c.6503G>T p.R2168I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99479303; called by muse, mutect2, varscan2
- CERS6 | c.576G>C p.L192F | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99987848; called by muse, mutect2, varscan2
- CERS6 | c.577A>T p.M193L | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99987851; called by muse, mutect2, varscan2
- CLP1 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 27/384 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100239953; called by muse, mutect2
- COL19A1 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507610; called by muse, mutect2, varscan2
- COL28A1 | c.2011G>T p.V671F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs1227089922, COSV101258966; called by muse, mutect2
- COL5A2 | c.2384G>A p.G795D | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66415614; called by muse, mutect2, varscan2
- CPT1B | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 92/469 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.34); catalogued as COSV56419157; called by muse, mutect2, varscan2
- CSMD1 | c.5785G>A p.G1929R (on ENST00000520002; = p.G1928R on NM_033225.6) | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745402367, COSV59287863; called by muse, mutect2, varscan2
- CYB5R4 | c.66dup p.R23Afs*2 | Frame Shift Ins (INS) | VAF 5/14 reads (36%) | catalogued as rs750790143; called by mutect2, varscan2
- DNAAF5 | c.2357G>T p.S786I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs747063911, COSV99860361; called by muse, mutect2
- DNHD1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99601050; called by muse, mutect2
- DOCK8 | c.5294T>C p.F1765S | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV101210093; called by muse, mutect2
- EIF4A3 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53921874, COSV53922151; called by muse, mutect2, varscan2
- ELOA | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV69311380; called by muse, mutect2, varscan2
- EPS15L1 | c.416T>C p.L139S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1228745048, COSV50176163; called by muse, mutect2, varscan2
- FABP12 | c.29A>T p.K10M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64617828; called by muse, mutect2, varscan2
- FAM237A | c.372A>C p.K124N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as COSV69305391; called by muse, mutect2, varscan2
- FAT3 | c.12685C>A p.Q4229K | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53177073; called by muse, mutect2, varscan2
- FBLN2 | c.3124T>C p.C1042R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55491389; called by mutect2, varscan2
- FGF5 | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56892016; called by muse, mutect2, varscan2
- FSD1 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs1434011951, COSV55696811; called by muse, mutect2, varscan2
- ICMT | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV59474674; called by muse, mutect2, varscan2
- KASH5 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV71358516; called by muse, mutect2, varscan2
- MAGEA11 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV60759018; called by muse, mutect2, varscan2
- MAPK7 | c.2408C>A p.S803Y | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV55189986, COSV55191927; called by muse, varscan2
- MCM10 | c.1233C>A p.Y411* (on ENST00000484800 / NM_182751.3; = p.Y410* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 22/407 reads (5%) | catalogued as COSV101098486, COSV66333154; called by muse, mutect2
- MED13 | c.3967+1G>C p.X1323_splice | Splice Site (SNP) | VAF 13/138 reads (9%) | catalogued as COSV101181435; called by muse, mutect2
- MICU3 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV58846113, COSV58849397; called by muse, mutect2, varscan2
- MUC17 | c.8351C>A p.T2784N | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV60293536, COSV60304106; called by muse, varscan2
- MYH1 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99821050; called by muse, mutect2
- MYO6 | c.3472C>T p.Q1158* (on ENST00000369981; = p.Q1148* on NM_004999.4) | Nonsense Mutation (SNP) | VAF 9/153 reads (6%) | catalogued as COSV100889433; called by muse, mutect2
- NDST2 | c.2580G>T p.K860N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs894195730, COSV55218129; called by muse, mutect2, varscan2
- OR13G1 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100687594; called by muse, mutect2
- OR3A2 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101375028, COSV68695302; called by muse, mutect2, varscan2
- OR5B17 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV62161113; called by muse, mutect2, varscan2
- OR5R1 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV100393608; called by muse, mutect2
- OR5V1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149477718, COSV65830482; called by muse, mutect2, varscan2
- OTULINL | c.445T>G p.F149V | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV57036599; called by muse, mutect2, varscan2
- PCCA | c.1168C>A p.R390S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66199163; called by muse, varscan2
- PDCD11 | c.2083C>A p.L695M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV100874428, COSV63935098; called by muse, mutect2
- PMEL | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.428); catalogued as COSV59388812; called by muse, mutect2, varscan2
- PREX1 | c.2387A>T p.Q796L | Missense Mutation (SNP) | VAF 481/551 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV64257112; called by muse, mutect2, varscan2
- PSMB4 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV51853370; called by muse, mutect2, varscan2
- PSMC4 | c.435dup p.E146Rfs*97 | Frame Shift Ins (INS) | VAF 10/114 reads (9%) | catalogued as rs747871663; called by mutect2, pindel
- PTH2R | c.1530C>A p.H510Q | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV55914761, COSV55920577; called by muse, varscan2
- PTPRH | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs756551259, COSV54750368; called by muse, varscan2
- RIN2 | c.2605C>T p.Q869* (on ENST00000255006 / NM_001242581.1; = p.Q820* on NM_018993.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/250 reads (12%) | catalogued as COSV54794485; called by muse, mutect2, varscan2
- RNF43 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.23); catalogued as COSV101348563; called by muse, mutect2
- SATB1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58668114; called by muse, mutect2, varscan2
- SH2D7 | c.559T>G p.S187A | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60927926; called by muse, mutect2, varscan2
- SLC6A15 | c.959T>G p.F320C | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57030085; called by muse, mutect2, varscan2
- SLFN13 | c.2285C>A p.A762E | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99540447; called by muse, mutect2
- SPTA1 | c.4823G>C p.R1608P | Missense Mutation (SNP) | VAF 122/221 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs781244377, COSV63753851, COSV63759960; called by muse, mutect2, varscan2
- STK36 | c.2682G>C p.E894D | Missense Mutation (SNP) | VAF 158/261 reads (61%) | SIFT tolerated (0.82); PolyPhen benign (0.109); catalogued as COSV55331094; called by muse, mutect2, varscan2
- STRA6 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs746151472, COSV60588714; called by muse, mutect2, varscan2
- SUSD4 | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV59556915; called by muse, mutect2, varscan2
- TAGAP | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV57853232; called by muse, mutect2
- TCERG1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57042264; called by muse, mutect2, varscan2
- TCTN3 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.416); catalogued as COSV99797700; called by muse, mutect2, varscan2
- TFDP1 | c.692T>G p.I231S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64742796; called by mutect2, varscan2
- TNFRSF9 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV101097385; called by muse, mutect2
- TRIOBP | c.1546T>C p.S516P | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV60384681; called by muse, mutect2, varscan2
- URI1 | c.1216C>G p.R406G | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100368951, COSV56353299; called by muse, mutect2, varscan2
- WDR6 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs148510310; called by muse, mutect2, varscan2
- YARS1 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV65115345; called by muse, mutect2, varscan2
- ZBTB11 | c.3124G>C p.V1042L | Missense Mutation (SNP) | VAF 151/260 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.314); catalogued as COSV57247126; called by muse, mutect2, varscan2
- ZBTB41 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100963475; called by muse, mutect2
- ZDHHC11 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99363678; called by mutect2, varscan2
- ZNF518A | c.682A>T p.R228* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as COSV60153549; called by muse, mutect2, varscan2
- ZNF521 | c.2378G>C p.G793A | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV64132151; called by muse, mutect2, varscan2
- ZNF521 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV64132152; called by muse, mutect2, varscan2
- ZNF701 | c.1088C>G p.P363R (on ENST00000301093; = p.P297R on NM_018260.3) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs778340607, COSV99991030; called by muse, varscan2
- ADAM29 | c.1127A>G p.E376G | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.124); called by muse, mutect2
- ATP2B4 | c.2420_2430del p.T807Kfs*11 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel
- COL6A3 | c.1423_1438del p.L475Ifs*14 | Frame Shift Del (DEL) | VAF 50/398 reads (13%) | called by mutect2, pindel
- MAGEE2 | c.499_509del p.R167Vfs*37 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- MYH13 | c.2518del p.I840Sfs*5 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- NUP214 | c.728-1G>T p.X243_splice | Splice Site (SNP) | VAF 14/149 reads (9%) | called by muse, varscan2
- OTOA | c.1849-3_1855del p.X617_splice (on ENST00000286149; = p.X603_splice on NM_144672.4) | Splice Site (DEL) | VAF 15/135 reads (11%) | called by mutect2, pindel, varscan2
- PSD3 | c.2120_2161del p.I707_S720del (on ENST00000440756; = p.I706_S719del on NM_015310.4) | In Frame Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- SLC17A4 | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- ZCCHC12 | c.1000_1044del p.E334_S348del | In Frame Del (DEL) | VAF 187/298 reads (63%) | called by mutect2, pindel
- ZNF140 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2
- AHNAK | c.8934G>A p.K2978= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as rs1384212549, COSV57231526; called by muse, mutect2, varscan2
- ALPK1 | c.2994T>C p.N998= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV99455258; called by muse, mutect2
- ANKRD12 | c.2163A>G p.E721= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV50850829; called by muse, mutect2, varscan2
- APOL5 | c.846C>A p.G282= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99968482; called by muse, mutect2
- ARID2 | c.3817C>A p.R1273= | Silent (SNP) | VAF 58/106 reads (55%) | catalogued as COSV57603720, COSV57615266; called by muse, mutect2, varscan2
- ATP2A3 | c.720G>C p.A240= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs552276386, COSV59235468; called by muse, mutect2, varscan2
- BAZ2A | c.2106G>A p.L702= | Silent (SNP) | VAF 12/394 reads (3%) | catalogued as COSV99467819; called by muse, mutect2
- BTBD7 | c.2670G>A p.E890= | Silent (SNP) | VAF 46/73 reads (63%) | catalogued as COSV58290732; called by muse, mutect2, varscan2
- C5orf24 | c.321C>G p.G107= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV100574588; called by muse, mutect2
- CATSPERG | c.2985C>T p.A995= | Silent (SNP) | VAF 46/570 reads (8%) | catalogued as COSV99286964; called by muse, mutect2
- CHD3 | c.5706C>T p.S1902= (on ENST00000330494 / NM_001005273.3; = p.S1868= on NM_005852.4) | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV57880622; called by muse, mutect2, varscan2
- CKAP4 | c.1188G>T p.S396= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as COSV65172289, COSV65173293; called by muse, mutect2, varscan2
- COBL | c.318A>G p.E106= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV54359317; called by muse, mutect2, varscan2
- CYP2B6 | c.234G>C p.L78= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV57845599; called by muse, mutect2, varscan2
- DNALI1 | c.510G>A p.L170= (on ENST00000296218; = p.L148= on NM_003462.5) | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV56171527; called by muse, mutect2, varscan2
- DRGX | c.606C>T p.R202= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV100938398; called by muse, mutect2
- DSG3 | c.12C>A p.L4= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV57129920; called by muse, mutect2, varscan2
- ELOVL7 | c.429G>A p.V143= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs776243961, COSV70918739; called by muse, mutect2, varscan2
- GGT7 | c.1383C>A p.L461= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV60542899; called by muse, mutect2, varscan2
- GIGYF2 | c.828G>C p.G276= | Silent (SNP) | VAF 39/287 reads (14%) | catalogued as rs368592394; called by muse, mutect2, varscan2
- GRM5 | c.2208C>A p.T736= | Silent (SNP) | VAF 22/301 reads (7%) | catalogued as COSV59593016; called by muse, mutect2
- HEATR5A | c.4572A>G p.E1524= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs1282441279, COSV66345931; called by muse, mutect2, varscan2
- KCNC1 | c.1230G>A p.T410= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as rs1295549018, COSV56395300; called by muse, mutect2, varscan2
- LHCGR | c.669G>T p.G223= | Silent (SNP) | VAF 26/370 reads (7%) | catalogued as COSV54304597, COSV99684128; called by muse, mutect2
- MKNK1 | c.616T>C p.L206= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV57863080; called by muse, mutect2, varscan2
- MYH4 | c.699C>T p.F233= | Silent (SNP) | VAF 85/139 reads (61%) | catalogued as rs780206832, COSV55117392; called by muse, mutect2, varscan2
- OLFM3 | c.15C>G p.S5= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV64462035; called by muse, mutect2, varscan2
- OR5K4 | c.312C>A p.L104= | Silent (SNP) | VAF 99/280 reads (35%) | catalogued as COSV100721292, COSV61584379; called by muse, varscan2
- OR7D4 | c.90G>C p.L30= | Silent (SNP) | VAF 55/277 reads (20%) | catalogued as COSV58072863; called by muse, mutect2, varscan2
- OR8U1 | c.507C>T p.C169= | Silent (SNP) | VAF 24/378 reads (6%) | catalogued as COSV100164151; called by muse, mutect2
- PARD3 | c.1107A>G p.L369= | Silent (SNP) | VAF 56/373 reads (15%) | catalogued as COSV60762765; called by muse, mutect2, varscan2
- PGM5 | c.1680G>A p.R560= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs1421427446, COSV67169162; called by muse, mutect2, varscan2
- PRKD1 | c.2499C>A p.T833= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV59587535; called by muse, mutect2, varscan2
- PSD4 | c.246C>T p.D82= | Silent (SNP) | VAF 63/79 reads (80%) | catalogued as rs147089589; called by muse, mutect2, varscan2
- RAP1GAP | c.87A>C p.P29= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV51578617; called by muse, mutect2, varscan2
- RTL9 | c.2442T>C p.A814= | Silent (SNP) | VAF 53/498 reads (11%) | catalogued as COSV71826474; called by muse, mutect2, varscan2
- TNFRSF8 | c.882C>A p.T294= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV55801023; called by muse, mutect2, varscan2
- VPS13B | c.4866C>A p.I1622= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV100663815, COSV62159276; called by muse, mutect2
- ZBTB24 | c.1245C>T p.F415= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as COSV57783820; called by muse, varscan2
- C5orf64 | n.512+51985G>C | Intron (SNP) | VAF 93/245 reads (38%) | called by muse, mutect2, varscan2
